Somatic mutation profile of tumor specimen MMRF_1725_1_BM_CD138pos (aliquot MMRF_1725_1_BM_CD138pos_T2_KBS5U_L05363) from MMRF case MMRF_1725, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.0 years (25,190 days).
Specimen MMRF_1725_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a853c7c-23e5-4e05-b4be-75c3557784f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1725_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1725_1_PB_Whole_C3_KBS5U_L05358; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27def04a-78c9-4e99-a4ab-14712f5851c0

The open-access MAF lists 66 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 12, Silent 9, Intron 7, Nonsense Mutation 4, 5'Flank 2, Splice Region 1, RNA 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL9 | c.2893G>A p.V965I | Missense Mutation (SNP) | VAF 161/426 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.097); catalogued as rs782070378; called by muse, mutect2, varscan2
- CD276 | c.337C>A p.R113S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as COSV59205535; called by muse, mutect2, varscan2
- CLPX | c.1087A>T p.I363F | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55647221; called by muse, mutect2, varscan2
- CPEB1 | c.1085G>A p.R362Q (on ENST00000617958; = p.R302Q on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs777735904; called by muse, mutect2
- EIF4G1 | c.2024G>A p.R675Q (on ENST00000346169 / NM_198241.3; = p.R479Q on NM_004953.5) | Missense Mutation (SNP) | VAF 108/219 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs777304254, COSV59992857; called by muse, mutect2, varscan2
- IKZF1 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs771544454; called by muse, mutect2, varscan2
- MRGPRX1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs183845903, COSV57106525; called by muse, mutect2, varscan2
- NUDT3 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV74119166; called by muse, mutect2, varscan2
- OPN3 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 114/190 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs1401259798; called by muse, mutect2, varscan2
- SETD3 | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as COSV59287391; called by muse, mutect2, varscan2
- USP7 | c.1657C>T p.Q553* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV61214288; called by muse, mutect2, varscan2
- WAPL | c.2981A>G p.Y994C | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1564564289; called by muse, mutect2, varscan2
- WNT9A | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 69/118 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs755900036; called by muse, mutect2, varscan2
- CLYBL | c.814A>T p.I272F | Missense Mutation (SNP) | VAF 39/40 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP2 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK7 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); called by muse, mutect2
- EIF4E1B | c.394A>G p.N132D | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- EXOC4 | c.766A>C p.R256= | Splice Region (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- FPGT | c.1498A>C p.I500L | Missense Mutation (SNP) | VAF 172/361 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MEGF6 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2
- NR2F1 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 105/235 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP214 | c.2854G>C p.A952P | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- PCDH11X | c.3323G>A p.G1108D | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH9 | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 78/140 reads (56%) | SIFT tolerated (0.83); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- RAD51AP2 | c.1376C>G p.S459* | Nonsense Mutation (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2
- RPS6KA4 | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- TBX3 | c.1637T>A p.V546D (on ENST00000257566 / NM_016569.4; = p.V526D on NM_005996.4) | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRAF3 | c.251dup p.S85Kfs*13 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- TTN | c.4372G>C p.V1458L (on ENST00000591111; = p.V1412L on NM_003319.4) | Missense Mutation (SNP) | VAF 77/165 reads (47%) | PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UFL1 | c.2218G>A p.V740I | Missense Mutation (SNP) | VAF 91/169 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- VSIG8 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- WASHC5 | c.3364G>T p.V1122F | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- WDFY3 | c.4133G>A p.G1378E | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZNF827 | c.1301A>G p.Q434R | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- ASXL3 | c.3639T>A p.S1213= | Silent (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- CFHR3 | c.942A>G p.S314= | Silent (SNP) | VAF 70/117 reads (60%) | called by muse, mutect2, varscan2
- DRD5 | c.333G>A p.A111= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV58578285; called by muse, mutect2, varscan2
- GRM6 | c.699C>T p.F233= | Silent (SNP) | VAF 57/174 reads (33%) | catalogued as rs367700792; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGHV3-74 | c.54G>A p.Q18= | Silent (SNP) | VAF 88/193 reads (46%) | called by muse, varscan2
- KIF26B | c.5460C>T p.G1820= | Silent (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- NUP188 | c.3999T>C p.T1333= | Silent (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- RB1CC1 | c.750T>C p.T250= | Silent (SNP) | VAF 132/247 reads (53%) | catalogued as rs1401696481; called by muse, mutect2, varscan2
- ZNF226 | c.1392C>G p.A464= | Silent (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2, varscan2
- ANXA11 | c.*4653A>C | 3'UTR (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- C3orf62 | c.*1989C>T | 3'UTR (SNP) | VAF 56/114 reads (49%) | called by muse, mutect2, varscan2
- CGB1 | chr19:49038638 G>A | 5'Flank (SNP) | VAF 11/51 reads (22%) | catalogued as rs1018798363; called by muse, mutect2, varscan2
- DNAJC8 | c.*151G>A | 3'UTR (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- DPP10 | c.*994T>G | 3'UTR (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- EDIL3 | c.1137+12144A>C | Intron (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- EXPH5 | c.*2151C>G | 3'UTR (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- FOXP1 | c.*1366C>G | 3'UTR (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- GABBR2 | c.*339G>A | 3'UTR (SNP) | VAF 9/23 reads (39%) | catalogued as COSV52315032; called by muse, mutect2, varscan2
- GALNT17 | c.*214G>A | 3'UTR (SNP) | VAF 45/148 reads (30%) | called by muse, mutect2, varscan2
- GPR68 | c.-130+2750G>C | Intron (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- IGHJ6 | chr14:105863437 A>T | 5'Flank (SNP) | VAF 12/23 reads (52%) | called by muse, varscan2
- KCNMB1 | c.306+212G>T | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- KLHL21 | c.1500+152T>G | Intron (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- LINC00632 | n.104+2428C>G | Intron (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- MAP4K2 | c.-18C>T | 5'UTR (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- NAA38 | c.265+19C>T | Intron (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- NSD1 | c.*2655A>G | 3'UTR (SNP) | VAF 28/57 reads (49%) | catalogued as rs1297382775; called by muse, mutect2, varscan2
- PDE3A | c.*1457del | 3'UTR (DEL) | VAF 25/56 reads (45%) | catalogued as rs955399397; called by mutect2, varscan2
- SLC38A2 | c.*2057_*2065del | 3'UTR (DEL) | VAF 24/73 reads (33%) | called by mutect2, pindel, varscan2
- SPATA31D5P | n.477G>T | RNA (SNP) | VAF 128/319 reads (40%) | called by muse, mutect2, varscan2
- TLN2 | c.*629C>T | 3'UTR (SNP) | VAF 18/276 reads (7%) | catalogued as rs1388496846; called by muse, mutect2
- UBE2D3 | c.120+43del | Intron (DEL) | VAF 29/60 reads (48%) | called by mutect2, pindel, varscan2
